Surgical pathology report (de-identified scan), TCGA case TCGA-J9-A52C, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Melbourne Health, specimen TCGA-J9-A52C-01A (Primary Tumor).

[page 1 of 2]
HISTOPATHOLOGY REPORT

CLINICAL NOTES :

PSA 7.4, T1c, Gleason 7/8 left side. tissue banking. Tissue banking

MACROSCOPIC :

A 46 g radical prostate, 55 x 35 x 45 mm

Block designation:

Block AB Right apex Block BC Left apex
Block DE Right base Block FG Left base
Blocks H to N Apex to base right, side blue Blocks O to U Apex to base left side green. sl
Block V Right seminal vesicles Block W Left seminal vesicles

MICROSCOPIC :

The sections show multifocal, bilateral adenocarcinoma. The index tumour is towards the left bladder base Gleason pattern **4+5=9**. The tumour shows direct infiltration into the left seminal vesicle and there is an adjacent 3 mm focus of extraprostatic extension. The overlying pathological margin is clear.

There is a small organ confined right apical transition zone adenocarcinoma, Gleason **3+3=6**. The right seminal vesicles and the pathological margins are clear. Tissue banking correctly identified. Index tumour sampled.

CONCLUSION:

Robotic radical prostatectomy -- multifocal, bilateral adenocarcinoma. Index tumour left side Gleason 4+5=9 with direct invasion of the seminal vesicles and adjacent extraprostatic extension (3 mm). Pathological margins clear, pT3b.

SYNOPTIC REPORT: CARCINOMA OF PROSTATE

Specimen type : Robotic radical prostatectomy -- tissue banking

Tumour type: Index tumour: adenocarcinoma nos

Other tumour foci: transition zone

Gleason score: Index tumour: 4+5=9

Other tumour foci: 4+4=8

Site: See volumetric analysis.

Unifocal/Multifocal : multifocal

Perineural invasion : present

Lymphovascular invasion : uncertain

Extraprostatic extension : positive left bladder neck 3 mm

Seminal vesicle involvement : Positive left seminal vesicles

Pathological resection margin status : negative

Presence of PIN : minimal

Lymph nodes: not taken

Tumour Volume: Peripheral Zone (black): 1.5cc

ICD-O-3

Path: adenocarcinoma, NOS 8140/3

CQCF: adenocarcinoma, acinar 8550/3

Site: prostate, NOS 61.9

hw

11/12/12

Prior Malignancy/History		

11/15/12

[page 2 of 2]
Transition Zone (green): 0.1cc

Pathologic stage: pT3b

Source: NCI Genomic Data Commons file 685a675c-5468-4f87-a555-5eefafd131a6 (TCGA-J9-A52C.CAAC3743-CE39-4A47-8D46-3C4917D469C1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).